Somatic mutation profile of tumor specimen TCGA-BR-8370-01A (aliquot TCGA-BR-8370-01A-11D-2340-08) from TCGA case TCGA-BR-8370, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 64.7 years (23,636 days).
Specimen TCGA-BR-8370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b215a02-8669-443e-9df0-ac742f80b39c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8370-10A (Blood Derived Normal), aliquot TCGA-BR-8370-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246626b2-af13-445a-bf15-b7e4229d94a3

The open-access MAF lists 124 somatic variants for this specimen: 90 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 33, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1724G>T p.S575I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV66141914; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV55946586; called by muse, mutect2, varscan2
- AC104389.6 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as rs1564884358, COSV100400578; called by muse, mutect2, varscan2
- ACCSL | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66580403; called by muse, mutect2, varscan2
- ADGRV1 | c.2301G>C p.L767F | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV101315583, COSV67979849; called by muse, mutect2, varscan2
- AFAP1 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs768741809, COSV61793838; called by muse, mutect2, varscan2
- AK7 | c.690+1G>A p.X230_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as rs764099443, COSV50869494; called by muse, mutect2, varscan2
- AMPD3 | c.1051C>T p.R351W (on ENST00000396553 / NM_001025389.2; = p.R360W on NM_000480.3) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs780915004, COSV67330088; called by muse, mutect2, varscan2
- ANKRD45 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.285); catalogued as COSV60960316; called by muse, mutect2, varscan2
- AQP8 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs557244284, COSV54844312; called by muse, mutect2, varscan2
- ARSK | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs149960886; called by muse, mutect2, varscan2
- ATP8A2 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54940778; called by muse, mutect2, varscan2
- BAX | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV53169319; called by muse, mutect2, varscan2
- C3 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1309838043, COSV55569923; called by muse, mutect2, varscan2
- C9orf135 | c.150C>T p.S50= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV65874726; called by muse, mutect2, varscan2
- CARMIL2 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs181809876; called by muse, mutect2, varscan2
- CCDC142 | c.654A>C p.K218N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs377134521; called by muse, mutect2, varscan2
- CCDC42 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs145016058; called by muse, mutect2, varscan2
- CCT8 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54503213; called by muse, mutect2, varscan2
- CDH1 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55728790, COSV55740273; called by muse, mutect2, varscan2
- CDH23 | c.8800G>T p.A2934S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as COSV56451569; called by muse, mutect2, varscan2
- CHD4 | c.3979C>T p.R1327C (on ENST00000357008 / NM_001363606.2; = p.R1340C on NM_001273.5) | Missense Mutation (SNP) | VAF 141/218 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58896099, COSV58902501; called by muse, mutect2, varscan2
- CNTNAP5 | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.762); catalogued as rs1361960256, COSV70476341; called by muse, mutect2, varscan2
- CPA1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1283286662, COSV50568278; called by muse, mutect2, varscan2
- CSGALNACT1 | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV59974726; called by muse, mutect2, varscan2
- CSMD1 | c.9157G>A p.D3053N (on ENST00000520002; = p.D3052N on NM_033225.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs753656504, COSV59280301; called by muse, mutect2, varscan2
- DBN1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as COSV52788004; called by muse, mutect2, varscan2
- DENND2A | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV52048555; called by muse, mutect2
- DYNAP | c.550G>T p.A184S (on ENST00000321600; = p.A158S on NM_173629.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV58666018, COSV58666862; called by muse, mutect2, varscan2
- EPHX3 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as rs897244496, COSV54583172; called by muse, mutect2
- ERBB4 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs761773013, COSV53509048; called by muse, mutect2, varscan2
- FAM110B | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV100826034; called by mutect2, varscan2
- FGF18 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51125451; called by muse, mutect2, varscan2
- FSTL1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369259187; called by muse, mutect2, varscan2
- GCN1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV56104784; called by muse, mutect2, varscan2
- GLI3 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs541487979, COSV67885995; called by muse, mutect2, varscan2
- GPANK1 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100788974; called by muse, mutect2, varscan2
- H2BC5 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.706); catalogued as rs776173606, COSV56799968, COSV56800111, COSV56800205; called by muse, mutect2
- HIVEP1 | c.890A>G p.H297R | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65099345; called by muse, mutect2
- HVCN1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs528631783, COSV54371403; called by muse, mutect2, varscan2
- IGLV3-21 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528720511; called by muse, mutect2, varscan2
- IL17C | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs368594752, COSV54918159; called by muse, mutect2, varscan2
- KCTD9 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 64/184 reads (35%) | catalogued as COSV55339435, COSV55340402; called by muse, mutect2, varscan2
- KLK13 | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.884); catalogued as COSV50066881; called by muse, mutect2
- LAD1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.201); catalogued as rs1009868369, COSV66212121; called by muse, mutect2, varscan2
- LINGO2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV58057864; called by muse, mutect2, varscan2
- LRBA | c.7555C>G p.P2519A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV63950993; called by muse, mutect2, varscan2
- LRP1 | c.4561C>A p.Q1521K | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV54504054; called by muse, mutect2, varscan2
- MED12L | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56371123; called by muse, mutect2, varscan2
- MITF | c.1469A>G p.D490G (on ENST00000448226 / NM_006722.3; = p.D390G on NM_000248.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58830132; called by muse, mutect2, varscan2
- MON2 | c.3410-2A>T p.X1137_splice | Splice Site (SNP) | VAF 6/126 reads (5%) | catalogued as COSV54804086; called by muse, mutect2
- MPDZ | c.4991C>A p.A1664E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59915840; called by muse, mutect2, varscan2
- MTRR | c.1784A>G p.D595G (on ENST00000264668; = p.D568G on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV52942137; called by muse, mutect2, varscan2
- NEFM | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99646991; called by muse, mutect2
- NELL1 | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV54244316; called by muse, mutect2, varscan2
- NKTR | c.3217G>A p.V1073M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV51769819, COSV99235038; called by muse, mutect2, varscan2
- NOP2 | c.1304C>T p.T435I (on ENST00000322166 / NM_001258308.2; = p.T431I on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs1176802288, COSV59109715; called by muse, mutect2, varscan2
- OR1J2 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58943897, COSV58944861; called by muse, mutect2, varscan2
- OR5T2 | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV57588115, COSV57590410; called by muse, mutect2, varscan2
- OR8B4 | c.500_502del p.F167del | In Frame Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1376694723; called by mutect2, pindel, varscan2
- PCDH10 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV52088878; called by muse, mutect2, varscan2
- PCDHB7 | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1554280131, COSV50756008; called by muse, mutect2, varscan2
- PDZD8 | c.2194G>T p.V732F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV57823801; called by muse, mutect2, varscan2
- PKHD1 | c.2419C>A p.Q807K | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV61863989; called by muse, mutect2, varscan2
- RASA3 | c.1284G>A p.E428= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100480062, COSV61864588; called by muse, mutect2, varscan2
- SAMD9L | c.1694G>T p.W565L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV59080097; called by muse, mutect2, varscan2
- SH3GL3 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs374787134; called by muse, mutect2, varscan2
- SLCO6A1 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65806467; called by muse, mutect2, varscan2
- SPTA1 | c.5409G>T p.K1803N | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV63749912; called by muse, mutect2, varscan2
- TMC2 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV62650439; called by muse, mutect2, varscan2
- TMEM132D | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746232750, COSV67158852; called by muse, mutect2, varscan2
- TNPO1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV61520426; called by muse, mutect2, varscan2
- TP53BP1 | c.4510G>T p.G1504W | Missense Mutation (SNP) | VAF 133/247 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55497201; called by muse, mutect2, varscan2
- TRAF3IP3 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981440427, COSV50550785, COSV50553080; called by muse, mutect2, varscan2
- TRPA1 | c.662-1G>T p.X221_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as rs748136716, COSV51556619; called by muse, mutect2
- TRPC3 | c.2701G>T p.E901* (on ENST00000379645 / NM_001366479.2; = p.E828* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV53372750, COSV53376421; called by muse, mutect2, varscan2
- TTN | c.11071C>G p.L3691V (on ENST00000591111; = p.L3645V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | catalogued as COSV59920070; called by muse, mutect2, varscan2
- WDR83OS | c.164G>A p.W55* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV54417429; called by muse, mutect2, varscan2
- WEE1 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.395); catalogued as COSV55196471, COSV55196495; called by muse, mutect2, varscan2
- WWOX | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV101282883; called by muse, mutect2, varscan2
- YPEL4 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773403127, COSV55518363; called by mutect2, varscan2
- ZBTB40 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs999201515, COSV65144772; called by muse, mutect2, varscan2
- ZNF184 | c.638C>A p.S213* | Nonsense Mutation (SNP) | VAF 52/187 reads (28%) | catalogued as COSV53003347; called by muse, mutect2, varscan2
- ZNF85 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as COSV56021154, COSV56022738; called by muse, mutect2, varscan2
- ATXN7 | c.2042G>C p.R681T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by mutect2, varscan2
- ATXN7 | c.2046_2054del p.K683_S685del | In Frame Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- DOCK8 | c.3917dup p.N1306Kfs*3 | Frame Shift Ins (INS) | VAF 19/93 reads (20%) | called by mutect2, pindel, varscan2
- SMAD4 | c.1160_1161dup p.Q388Cfs*28 | Frame Shift Ins (INS) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- TNKS1BP1 | c.417del p.G141Vfs*86 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- ARL6IP5 | c.27C>T p.R9= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV56234461; called by muse, mutect2, varscan2
- ASTL | c.756A>G p.T252= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1188833133, COSV60903700; called by muse, mutect2, varscan2
- BANK1 | c.525T>C p.S175= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV59839475; called by muse, mutect2, varscan2
- COL12A1 | c.3258G>T p.R1086= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV59391132; called by muse, mutect2, varscan2
- DUSP5 | c.15G>A p.S5= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs777773018, COSV63645345; called by muse, mutect2, varscan2
- EFHB | c.927C>T p.Y309= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs192099278, COSV55545406, COSV55550561; called by muse, mutect2, varscan2
- FCRL6 | c.816G>A p.G272= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58940219; called by muse, mutect2, varscan2
- FTCD | c.165G>A p.P55= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs143451664; called by muse, mutect2, varscan2
- GRIN2C | c.1464C>T p.R488= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs375716366; called by muse, mutect2, varscan2
- HTR1A | c.921G>T p.L307= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV60500068; called by muse, mutect2, varscan2
- HTT | c.2469C>T p.C823= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as COSV61858394; called by muse, mutect2, varscan2
- IGHV3-33 | c.87C>T p.G29= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs558677996; called by muse, mutect2, varscan2
- IGSF10 | c.2277G>T p.L759= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56782442; called by muse, mutect2, varscan2
- IRF1 | c.129G>A p.K43= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV55376264; called by muse, mutect2
- JPH2 | c.1665G>T p.S555= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV65902142; called by muse, mutect2
- KCNK9 | c.510G>A p.T170= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV57278978; called by muse, mutect2, varscan2
- KIAA1210 | c.4458G>A p.S1486= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs771385213, COSV68175880; called by muse, mutect2, varscan2
- KMT2C | c.2841T>C p.F947= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV51365282; called by muse, mutect2, varscan2
- LCOR | c.3915C>T p.A1305= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs1247166396, COSV53714750; called by muse, mutect2, varscan2
- MAP1B | c.3771G>A p.P1257= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs757277389, COSV57095053; called by muse, mutect2, varscan2
- MAPT | c.1881G>A p.S627= (on ENST00000262410 / NM_001377265.1; = p.S235= on NM_005910.5) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs115142761; called by muse, mutect2, varscan2
- MEOX2 | c.759G>A p.A253= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs755958618, COSV56288207; called by muse, mutect2, varscan2
- NEK10 | c.1833G>A p.P611= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs758416963, COSV58280826; called by muse, mutect2
- NEUROD1 | c.741C>T p.H247= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV54548080, COSV54548166; called by muse, mutect2, varscan2
- NF1 | c.5997C>T p.S1999= (on ENST00000358273 / NM_001042492.3; = p.S1978= on NM_000267.3) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV62195429; called by muse, mutect2, varscan2
- NOD1 | c.873G>A p.S291= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs555848797, COSV56111136; called by muse, mutect2, varscan2
- NRCAM | c.3762C>T p.S1254= (on ENST00000379028 / NM_001371124.1; = p.S1133= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 43/215 reads (20%) | catalogued as COSV61032316; called by muse, mutect2, varscan2
- OCM | c.270G>A p.A90= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs373499237; called by muse, mutect2, varscan2
- POLR2F | c.33C>T p.D11= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs747162109, COSV50777728; called by muse, mutect2, varscan2
- PPP1R13L | c.2202C>T p.C734= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1254996543, COSV62908043; called by muse, mutect2, varscan2
- TMEM199 | c.363C>T p.N121= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs376471654; called by muse, mutect2, varscan2
- ULK4 | c.3816C>T p.A1272= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs781157144, COSV57201302; called by muse, mutect2, varscan2
- ZNF560 | c.1419A>G p.S473= | Silent (SNP) | VAF 52/318 reads (16%) | catalogued as rs778070721, COSV56866238; called by muse, mutect2, varscan2
- ELMOD1 | c.-86+991G>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99759685; called by muse, mutect2, varscan2
